Gene-level copy-number profile of tumor specimen TCGA-B6-A1KF-01A from TCGA case TCGA-B6-A1KF, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 68.1 years (24,891 days).
Specimen TCGA-B6-A1KF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.2b07b60b-de7c-4b22-a292-8a30c10dab05.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B6-A1KF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8bd80d25-59cc-4786-9a77-8315f9f2b495

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 397; copy number 2: 24,273; copy number 3: 21,097; copy number 4: 7,403; copy number 5: 1,078; copy number 6: 253; copy number 7: 622; copy number 8: 427; copy number 9: 3,986; copy number 12: 201; copy number 28: 40; copy number 43: 40.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B6-A1KF-01A-11D-A13J-01): tumor purity 0.81, ploidy 3.23, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,618 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:118,712,999–248,919,946, 2,683 genes, copy number 9–43 (broad region; genes not listed).
- chr5:58,198–9,045,940, 186 genes, copy number 5 (broad region; genes not listed).
- chr5:33,888,056–45,895,970, 200 genes, copy number 5–6 (broad region; genes not listed).
- chr6:32,184,733–61,241,311, 614 genes, copy number 5–8 (broad region; genes not listed).
- chr7:125,917,871–125,933,832, 1 gene, copy number 7: AC003975.1.
- chr8:42,537,529–145,066,685, 1,575 genes, copy number 8–9 (broad region; genes not listed).
- chr10:44,712–38,762,491, 674 genes, copy number 5–9 (broad region; genes not listed).
- chr10:73,995,193–75,431,588, 36 genes, copy number 6 (within-gene range 3–6): VCL, AL596247.1, AP3M1, ADK, TIMM9P1, RPSAP6, RAB5CP1, AC022540.1, MRPL35P3, Y_RNA, NDUFA8P1, POLR3DP1, FAM32CP, AC063962.1, KAT6B, AC018511.2, AC018511.1, DUSP29, AC018511.6, PPIAP13, DUSP13, SAMD8, RPS26P42, VDAC2, COMTD1, ZNF503-AS1, RPL39P25, HMGA1P5, AC010997.3, AC010997.1, SPA17P1, ZNF503, ZNF503-AS2, AC010997.5, AC010997.4, AC010997.2.
- chr17:26,989,189–29,930,276, 164 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr17:34,574,123–41,624,842, 355 genes, copy number 5–28 (broad region; genes not listed).
- chr18:47,390–6,463,015, 130 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 397. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
